Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-5689, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-5689-01A (Primary Tumor).

DIAGNOSIS

(A) PART OF 12TH RIB:

Segment of rib for gross inspection only.

(B) LEFT KIDNEY:

RENAL CELL CARCINOMA, CONVENTIONAL (60% CLEAR CELLS AND 40% EOSINOPHILIC CELLS), FUHRMAN'S NUCLEAR GRADE 4. (SEE COMMENT)

TUMOR MEASURES 6.5 CM IN MAXIMUM DIMENSION.

Vascular, urethral and soft tissue margins of resection are free of tumor.

Renal cortical (simple) cysts, multiple (ranging from 0.1 to 6.0 cm in maximum dimension).

COMMENT

The tumor is within a vascular space in the renal sinus but does not invade the renal sinus adipose tissue. The tumor focally bulges into the perinephric adipose tissue; however, it does not infiltrate it. Multiple additional deeper sections were examined.

GROSS DESCRIPTION

(A) PART OF 12TH RIB, GROSS ONLY - A tan-pink irregular fragment of rib (5.0 x 1.4 x 0.3 cm). The specimen is entirely submitted for gross only. [REDACTED]

(B) LEFT KIDNEY- A nephrectomy specimen (23.5 x 13.5 x 7.5 cm) including the left kidney (13.0 x 7.5 x 7.3 cm), a segment of renal artery, renal vein, and ureter (7.8 cm in length and 0.4 cm in average diameter). Also present are three detached fragments of adipose tissue (16 x 12 x 4.5 cm in aggregate).

There is a 6.5 x 4.5 x 2.5 cm well-circumscribed tumor in the upper pole/mid portion of the kidney. The tumor is yellow, with focal areas of hemorrhage and necrosis, which are within the center of the tumor and solid tan areas. The tumor does appear to invade the renal sinus; however, it does not invade the perinephric adipose tissue and renal vein. The tumor does not extend into Gerota's fascia.

The adjacent kidney parenchyma demonstrates multiple cysts with the largest cyst measuring up to 6 cm in greatest dimension. The pelvicalyceal system is smooth and contains two brown-tan stones, which measure approximately 0.3 cm in greatest dimension. No lymph nodes are identified within the hilum of the kidney.

Portions of the tumor have been submitted for possible electron microscopy as well as other research protocols.

INK CODE: Blue - Gerota's fascia.

SECTION CODE: B1, ureter, renal vein, and renal artery margins; B2-B7, tumor with capsule and adipose tissue; B8-B11, tumor with sinus and pelvis; B12-B13, cysts; B14-B15, representative sections through adipose tissue. [REDACTED]

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-83123

Source: NCI Genomic Data Commons file 2a9f2f28-149b-4bc7-9f64-da33689b7906 (TCGA-CJ-5689.C47345FA-DF3E-4993-985E-1D1A877E9BCB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).